Somatic mutation profile of tumor specimen TCGA-C5-A7CK-01A (aliquot TCGA-C5-A7CK-01A-11D-A32I-09) from TCGA case TCGA-C5-A7CK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.9 years (21,520 days).
Specimen TCGA-C5-A7CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6d53522-d008-4898-ae9e-214ffedb2326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7CK-10A (Blood Derived Normal), aliquot TCGA-C5-A7CK-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29bccb22-441d-4426-801c-a98f8688aa02

The open-access MAF lists 137 somatic variants for this specimen: 105 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 30, Nonsense Mutation 12, Splice Site 5, Frame Shift Del 5, Splice Region 4, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.7977-1G>A p.X2659_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as rs81002874, CS030294, CS1311379, COSV66448512; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NLRP3 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121908153, CM021071, CM076355, COSV60219065; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.1251_1252del p.R418Sfs*9 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs1131690889; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACAD11 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99391586; called by muse, mutect2
- ADCY9 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs142198070; called by muse, mutect2, varscan2
- AJAP1 | c.1164-1G>A p.X388_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as COSV65454010; called by muse, mutect2, varscan2
- APLNR | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373170562, COSV57241687; called by muse, mutect2
- ARHGAP5 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100565015; called by muse, mutect2, varscan2
- B2M | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV62564161, COSV62565283; called by muse, mutect2, varscan2
- B3GAT1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs1374536721; called by muse, mutect2, varscan2
- CANX | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs756081134; called by muse, mutect2, varscan2
- CDC7 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750602155; called by muse, mutect2, varscan2
- CDH2 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs140836073; called by muse, mutect2, varscan2
- CIB1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV60173800; called by muse, mutect2
- CNTLN | c.361-2A>C p.X121_splice | Splice Site (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99262862; called by muse, mutect2, varscan2
- COL12A1 | c.3268C>T p.P1090S | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV59393256; called by muse, mutect2, varscan2
- COL27A1 | c.4844C>T p.P1615L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145134644, COSV61927109; called by muse, mutect2, varscan2
- COQ10A | c.282G>T p.G94= | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100369906; called by muse, mutect2
- DCC | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 38/58 reads (66%) | catalogued as rs1354970657; called by muse, mutect2, varscan2
- DCP2 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs776321450, COSV66617267; called by muse, mutect2, varscan2
- DDX50 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV101007313; called by mutect2, varscan2
- DEK | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.794); catalogued as COSV99788693; called by muse, mutect2
- DTNA | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371363393, COSV52011927; called by muse, mutect2, varscan2
- ECI2 | c.499G>A p.E167K (on ENST00000380118 / NM_206836.3; = p.E137K on NM_006117.2) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as rs1204495447; called by muse, mutect2, varscan2
- FGD5 | c.2177G>C p.R726T | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as rs766470996; called by muse, mutect2, varscan2
- GFPT1 | c.1153C>T p.R385W (on ENST00000357308 / NM_001244710.2; = p.R367W on NM_002056.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289816770; called by muse, mutect2, varscan2
- GGT5 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as rs765031471, COSV54069966; called by muse, mutect2, varscan2
- GOLIM4 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as rs1326686446, COSV100462656; called by muse, mutect2, varscan2
- GRAMD1B | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs763079105; called by muse, mutect2, varscan2
- HEATR5B | c.4594C>T p.L1532F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99248279; called by muse, mutect2, varscan2
- KCNS3 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1398464477, COSV58409222; called by muse, mutect2
- LILRA2 | c.377C>G p.S126* | Nonsense Mutation (SNP) | VAF 42/510 reads (8%) | catalogued as COSV52190703, COSV52198854; called by muse, mutect2
- MYBPC2 | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs539054221; called by muse, mutect2, varscan2
- MYH9 | c.4333_4335del p.K1445del | In Frame Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs889313598; called by pindel, varscan2
- NAV3 | c.4947G>C p.Q1649H | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.653); catalogued as rs1254436017; called by muse, mutect2, varscan2
- NFKBIE | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | PolyPhen benign (0.022); catalogued as COSV99069956; called by muse, mutect2, varscan2
- NLRP13 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs1239345881, COSV100738355; called by muse, mutect2, varscan2
- NLRP13 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1383536583; called by muse, mutect2, varscan2
- NLRP13 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs1462958155, COSV61620878, COSV61624212; called by muse, mutect2, varscan2
- NNMT | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs141072720, COSV55473919; called by muse, mutect2, varscan2
- NOTCH3 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs1428777171, COSV54650330; called by muse, mutect2, varscan2
- NPLOC4 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.045); catalogued as rs1378278966, COSV58618874; called by muse, mutect2, varscan2
- OR8K5 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100537266; called by muse, mutect2, varscan2
- PCBP2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV63728094, COSV63729423; called by muse, mutect2, varscan2
- PPP1R16B | c.1172C>A p.T391K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs901625179, COSV55375678; called by muse, mutect2, varscan2
- PPP2R1A | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100436059; called by muse, mutect2
- SHKBP1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1196932689; called by muse, mutect2, varscan2
- SPATA13 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs752240893; called by muse, mutect2, varscan2
- ST8SIA4 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs1417489878, COSV51505230; called by muse, mutect2, varscan2
- TCN1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs371448135; called by muse, mutect2, varscan2
- TERT | c.1880C>A p.P627H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV57226316; called by muse, mutect2, varscan2
- TGFBR2 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 25/35 reads (71%) | catalogued as rs1215812419, COSV55450155; called by muse, mutect2, varscan2
- TM4SF19 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs750021035; called by muse, mutect2, varscan2
- TUB | c.523C>T p.R175W (on ENST00000299506 / NM_177972.3; = p.R230W on NM_003320.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs752675874; called by muse, mutect2, varscan2
- UBOX5 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1462523072, COSV99417416; called by muse, mutect2, varscan2
- XPNPEP1 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs946351042; called by muse, mutect2, varscan2
- YLPM1 | c.4120C>T p.R1374* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs766434155, COSV53112298; called by muse, mutect2, varscan2
- AFF3 | c.2660C>G p.S887C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ATF7IP | c.2194G>C p.V732L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BLOC1S5 | c.1_47del p.M1_?16 | Frame Shift Del (DEL) | VAF 23/47 reads (49%) | called by mutect2, pindel
- BRPF1 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA2D2 | c.2432G>A p.R811K (on ENST00000479441 / NM_001174051.3; = p.R804K on NM_006030.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC14B | c.1491G>T p.L497F (on ENST00000375241 / NM_033331.4; = p.L458F on NM_003671.5) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTNAP1 | c.4057C>G p.P1353A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- COLEC10 | c.499A>T p.K167* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- DMWD | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DNAH6 | c.2091G>A p.M697I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EDRF1 | c.636-2A>G p.X212_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- FAT3 | c.3530C>T p.S1177F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2
- FRMD3 | c.1156del p.S386Pfs*27 | Frame Shift Del (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- HECTD4 | c.12490G>T p.D4164Y | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA5 | c.2727+2dup | Splice Region (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- KHDC4 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- KIAA1217 | c.5714C>G p.S1905* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4808C>T p.T1603I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT2D | c.7535_7550del p.S2512Ifs*26 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- LAMB2 | c.4223T>C p.L1408P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- LPIN2 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MDGA2 | c.989C>T p.T330I (on ENST00000399232 / NM_001113498.2; = p.T32I on NM_182830.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MOV10L1 | c.3475G>C p.G1159R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTX2 | c.207T>G p.S69= | Splice Region (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- MUC16 | c.38434T>C p.Y12812H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIPSNAP2 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NT5C1B | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- OR10W1 | c.838A>C p.I280L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PEX11A | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEK2 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- RTP5 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCRIB | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFTPA1 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC4A1AP | c.1374G>A p.W458* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- STRA6 | c.600C>A p.I200= | Splice Region (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- SULT1C4 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TARBP1 | c.4071+1G>T p.X1357_splice | Splice Site (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- TBCB | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TEX11 | c.2491T>C p.S831P (on ENST00000344304; = p.S816P on NM_031276.3) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- TMED8 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TOPBP1 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- TRIM58 | c.1370T>C p.I457T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRIM67 | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- UBE2B | c.282_295del p.R95Ifs*2 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- VPS37C | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- VWF | c.3683A>T p.D1228V | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- WASHC1 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 29/271 reads (11%) | called by muse, mutect2, varscan2
- ZNF519 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ATP8B4 | c.1002C>G p.L334= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1483779704; called by muse, mutect2, varscan2
- CDH10 | c.186C>T p.F62= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as COSV52604375; called by muse, mutect2
- CHST1 | c.744C>T p.R248= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV57322577; called by muse, mutect2, varscan2
- DNAL4 | c.150C>T p.N50= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1246446833, COSV99326045; called by muse, mutect2, varscan2
- EVPL | c.5694C>T p.N1898= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs765848119, COSV100043977; called by muse, mutect2, varscan2
- FGD5 | c.1977G>A p.L659= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99547624; called by muse, mutect2, varscan2
- FRMD6 | c.1635C>T p.L545= (on ENST00000344768 / NM_001267046.2; = p.L537= on NM_152330.4) | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1179548355, COSV100656348; called by muse, mutect2, varscan2
- FXR2 | c.1773C>T p.R591= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- HEG1 | c.930G>A p.E310= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs955839803; called by muse, mutect2, varscan2
- HIPK4 | c.48C>G p.V16= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- HNRNPK | c.1185C>T p.P395= | Silent (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- ITPKB | c.2439C>T p.I813= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs758611248; called by muse, mutect2, varscan2
- MYO16 | c.4122G>A p.A1374= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV62752985; called by muse, mutect2, varscan2
- NCKAP5 | c.5334C>T p.D1778= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs370892586; called by muse, mutect2, varscan2
- NKG7 | c.54C>T p.F18= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs762926859; called by muse, mutect2, varscan2
- NOD1 | c.2157C>T p.G719= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs201638077, COSV56112984; called by muse, mutect2, varscan2
- PCDHGA2 | c.1668C>T p.N556= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV53894618; called by muse, mutect2, varscan2
- PLEKHA5 | c.93G>A p.E31= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1201259702; called by muse, mutect2, varscan2
- POR | c.375G>C p.L125= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101203478; called by muse, mutect2
- PRAMEF17 | c.798G>A p.L266= | Silent (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- SHOX | c.330C>T p.D110= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs1035840052; called by muse, mutect2, varscan2
- SMCR8 | c.675C>T p.Y225= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs763305503; called by muse, mutect2, varscan2
- SMG1 | c.6969C>G p.V2323= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- STOML3 | c.621G>A p.E207= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1366752631; called by muse, mutect2, varscan2
- THOP1 | c.612G>C p.L204= | Silent (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- TMEM259 | c.630C>T p.I210= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as rs757361940, COSV99312208; called by muse, mutect2
- UBR4 | c.14973G>A p.P4991= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs185411354, COSV100920234; called by muse, mutect2, varscan2
- VPS37C | c.141G>A p.R47= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs1374727900; called by muse, mutect2, varscan2
- ZER1 | c.2127C>T p.L709= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1217863421, COSV52565463, COSV52567463; called by muse, mutect2, varscan2
- ZFP57 | c.822C>T p.L274= | Silent (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6282C>A | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6283G>T | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
